Gene-level copy-number profile of tumor specimen TCGA-KQ-A41N-01A from TCGA case TCGA-KQ-A41N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Ureteric orifice; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.5 years (26,837 days).
Specimen TCGA-KQ-A41N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cd3018a7-8f01-4ab6-a8ca-886035fa3b66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KQ-A41N-10D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02881b17-f6ab-4394-afe4-3787a98d0db5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,306; copy number 2: 43,935; copy number 3: 4,041; copy number 4: 260; copy number 5: 1,277.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KQ-A41N-01A-11D-A338-01): tumor purity 0.76, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,277 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:3,177,835–4,440,259, 10 genes, copy number 5: LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3.
- chr5:4,512,262–4,516,776, 1 gene, copy number 5: AC106799.1.
- chr8:36,277,763–36,779,209, 9 genes, copy number 5: MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264.
- chr8:36,795,255–36,795,862, 1 gene, copy number 5: AC124076.1.
- chr8:51,319,577–52,022,974, 10 genes, copy number 5 (within-gene range 2–5): PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3.
- chr8:52,150,820–52,199,580, 2 genes, copy number 5 (within-gene range 2–5): AC021915.2, AC021915.1.
- chr8:65,377,592–76,308,315, 177 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:76,904,591–145,066,685, 1,067 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,925. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
